Somatic mutation profile of tumor specimen TCGA-D1-A165-01A (aliquot TCGA-D1-A165-01A-11D-A12J-09) from TCGA case TCGA-D1-A165, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Endometrium; FIGO stage: Stage IIIA; Tumor grade: G1; Age at diagnosis: 64.4 years (23,526 days).
Specimen TCGA-D1-A165-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e56352a9-d812-4c4b-8a95-b13682abf9ee.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-D1-A165-10A (Blood Derived Normal), aliquot TCGA-D1-A165-10A-01D-A12J-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f4cd8eec-70c0-4f2e-80ab-3f90c538a128

The open-access MAF lists 72 somatic variants for this specimen: 54 protein-altering or splice-affecting, 17 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 41, Silent 17, Nonsense Mutation 6, In Frame Del 2, Frame Shift Ins 2, Frame Shift Del 2, Intron 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ACTN1 | c.2212C>T p.R738W | Missense Mutation (SNP) | VAF 44/127 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs387907349, CM138027, COSV51998076; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- CTNNB1 | c.97T>C p.S33P | Missense Mutation (SNP) | VAF 8/91 reads (9%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1057519886, COSV62688086, COSV62689225, COSV62704131; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- CTNNB1 | c.98C>A p.S33Y | Missense Mutation (SNP) | VAF 18/92 reads (20%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121913400, COSV62687839, COSV62688300, COSV62688644; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- PTEN | c.783_784del p.N262Qfs*35 | Frame Shift Del (DEL) | VAF 113/309 reads (37%) | catalogued as rs1554825249; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- ADGRD1 | c.1442C>T p.P481L | Missense Mutation (SNP) | VAF 50/117 reads (43%) | SIFT deleterious (0); PolyPhen benign (0.204); catalogued as rs774477089, COSV55458395; called by muse, mutect2, varscan2
- AFM | c.842C>T p.T281M | Missense Mutation (SNP) | VAF 139/340 reads (41%) | SIFT tolerated (0.16); PolyPhen benign (0.003); catalogued as rs764897369, COSV56920617; called by muse, mutect2, varscan2
- AP4M1 | c.407C>G p.T136R | Missense Mutation (SNP) | VAF 54/193 reads (28%) | SIFT tolerated (0.06); PolyPhen benign (0.332); catalogued as COSV57999175; called by muse, mutect2, varscan2
- ARHGAP35 | c.28C>T p.R10* | Nonsense Mutation (SNP) | VAF 70/165 reads (42%) | catalogued as COSV68329354; called by muse, mutect2, varscan2
- BLZF1 | c.646C>T p.R216* | Nonsense Mutation (SNP) | VAF 76/201 reads (38%) | catalogued as rs763271139, COSV61393623; called by muse, mutect2, varscan2
- BMF | c.142C>T p.Q48* | Nonsense Mutation (SNP) | VAF 31/90 reads (34%) | catalogued as COSV55019656; called by muse, mutect2, varscan2
- BRINP1 | c.2282G>A p.C761Y | Missense Mutation (SNP) | VAF 39/281 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as rs1427543202, COSV56314073; called by muse, mutect2, varscan2
- CHM | c.1757A>G p.N586S | Missense Mutation (SNP) | VAF 119/299 reads (40%) | SIFT tolerated (0.28); PolyPhen benign (0.005); catalogued as COSV63304834; called by muse, mutect2, varscan2
- CLCN5 | c.1660C>T p.R554W | Missense Mutation (SNP) | VAF 87/219 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.676); catalogued as COSV56584309; called by muse, mutect2, varscan2
- CTNND1 | c.950G>A p.R317H | Missense Mutation (SNP) | VAF 11/29 reads (38%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.996); catalogued as rs764156809, COSV62386405; called by muse, mutect2, varscan2
- DRAM1 | c.442T>C p.C148R | Missense Mutation (SNP) | VAF 130/334 reads (39%) | SIFT tolerated (0.35); PolyPhen possibly damaging (0.621); catalogued as rs745515371, COSV51600531; called by muse, mutect2, varscan2
- EXTL3 | c.2231A>T p.D744V | Missense Mutation (SNP) | VAF 102/197 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55040662; called by muse, mutect2, varscan2
- FDX2 | c.451C>T p.R151W | Missense Mutation (SNP) | VAF 24/100 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs750821339, COSV58534018; called by muse, mutect2, varscan2
- ICE1 | c.6443G>A p.W2148* | Nonsense Mutation (SNP) | VAF 48/269 reads (18%) | catalogued as COSV56833038; called by muse, mutect2, varscan2
- IMPG1 | c.2316G>A p.K772= | Splice Region (SNP) | VAF 138/421 reads (33%) | catalogued as rs771935979, COSV63113230; called by muse, mutect2, varscan2
- INPP4A | c.625C>T p.R209* | Nonsense Mutation (SNP) | VAF 26/233 reads (11%) | catalogued as rs1559033620, COSV50811540, COSV99302166; called by muse, mutect2, varscan2
- INPP4A | c.2671C>T p.R891W (on ENST00000074304 / NM_001134224.1; = p.R852W on NM_001566.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 9/24 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50815476; called by muse, mutect2, varscan2
- KIR3DL3 | c.862G>A p.G288R | Missense Mutation (SNP) | VAF 108/286 reads (38%) | SIFT tolerated (0.06); PolyPhen benign (0.13); catalogued as rs1336385457; called by muse, mutect2
- LIMS2 | c.668T>A p.V223D (on ENST00000355119 / NM_001161403.3; = p.V247D on NM_017980.4) | Missense Mutation (SNP) | VAF 36/92 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.674); catalogued as COSV61444987; called by muse, mutect2, varscan2
- MAP11 | c.1307C>T p.T436M | Missense Mutation (SNP) | VAF 5/46 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.764); catalogued as rs1469433483, COSV57588365; called by muse, mutect2, varscan2
- MECOM | c.686C>G p.T229R (on ENST00000468789 / NM_001105078.4; = p.T417R on NM_004991.4) | Missense Mutation (SNP) | VAF 192/757 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52958933, COSV52961988, COSV52975844; called by muse, varscan2
- MECOM | c.613C>A p.R205S (on ENST00000468789 / NM_001105078.4; = p.R393S on NM_004991.4) | Missense Mutation (SNP) | VAF 262/669 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52963046, COSV52964249, COSV52973072; called by muse, varscan2
- MTSS1 | c.1967G>T p.G656V | Missense Mutation (SNP) | VAF 82/236 reads (35%) | SIFT tolerated (0.12); PolyPhen benign (0.006); catalogued as COSV52676364; called by muse, mutect2, varscan2
- NYNRIN | c.4857C>G p.I1619M | Missense Mutation (SNP) | VAF 17/50 reads (34%) | SIFT tolerated (0.18); PolyPhen benign (0.15); catalogued as COSV66841670, COSV66845273; called by muse, mutect2, varscan2
- PHKA1 | c.2090G>T p.C697F | Missense Mutation (SNP) | VAF 71/188 reads (38%) | SIFT tolerated (0.46); PolyPhen benign (0); catalogued as COSV59812126; called by muse, mutect2, varscan2
- PIK3R1 | c.1925delinsCC p.R642Pfs*12 (on ENST00000521381 / NM_181523.3; = p.R372Pfs*12 on NM_181504.4) | Frame Shift Ins (INS) | VAF 48/266 reads (18%) | catalogued as COSV57132411, COSV57140561; called by mutect2*, pindel, varscan2*
- PLCZ1 | c.1658G>C p.R553P | Missense Mutation (SNP) | VAF 55/259 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56859151; called by muse, mutect2, varscan2
- PLS1 | c.1141C>A p.P381T | Missense Mutation (SNP) | VAF 28/277 reads (10%) | SIFT tolerated (0.07); PolyPhen benign (0.156); catalogued as COSV61835605; called by muse, mutect2
- PROS1 | c.1336C>G p.L446V | Missense Mutation (SNP) | VAF 5/144 reads (3%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV67777402; called by muse, mutect2
- PTCH2 | c.1307C>T p.A436V | Missense Mutation (SNP) | VAF 7/22 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.817); catalogued as rs753185169, CM083056, COSV64710162; called by muse, mutect2, varscan2
- PTEN | c.334C>G p.L112V | Missense Mutation (SNP) | VAF 186/503 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as CM031337, CM110155, COSV64293200; called by muse, mutect2, varscan2
- PTPN14 | c.1330G>T p.D444Y | Missense Mutation (SNP) | VAF 22/169 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as COSV65288925; called by muse, mutect2, varscan2
- RNF121 | c.607T>C p.Y203H | Missense Mutation (SNP) | VAF 53/190 reads (28%) | SIFT tolerated (0.36); PolyPhen benign (0.003); catalogued as COSV62317975; called by muse, varscan2
- SCN8A | c.4893C>G p.I1631M | Missense Mutation (SNP) | VAF 62/293 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV61993591; called by muse, mutect2, varscan2
- SLC16A5 | c.895G>A p.A299T | Missense Mutation (SNP) | VAF 34/91 reads (37%) | SIFT tolerated (0.43); PolyPhen benign (0.173); catalogued as COSV61677039; called by muse, mutect2, varscan2
- SLC22A6 | c.991C>T p.R331C | Missense Mutation (SNP) | VAF 32/85 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs150409056, COSV64561181; called by muse, mutect2, varscan2
- SLC30A8 | c.541G>A p.V181I | Missense Mutation (SNP) | VAF 14/390 reads (4%) | SIFT deleterious (0.02); PolyPhen benign (0.227); catalogued as rs1267353057, COSV69969913; called by muse, mutect2
- SMG1 | c.5644A>G p.I1882V | Missense Mutation (SNP) | VAF 69/166 reads (42%) | SIFT tolerated (0.33); PolyPhen benign (0.011); catalogued as rs755316887, COSV67174960; called by muse, mutect2, varscan2
- SPATA31E1 | c.1307G>A p.R436H | Missense Mutation (SNP) | VAF 19/46 reads (41%) | SIFT tolerated (0.35); PolyPhen benign (0.017); catalogued as rs780484019, COSV57793213; called by muse, mutect2, varscan2
- TMEM60 | c.203G>A p.R68Q | Missense Mutation (SNP) | VAF 108/302 reads (36%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.898); catalogued as rs779804125, COSV51899155; called by muse, mutect2, varscan2
- TRAP1 | c.1204C>T p.R402W | Missense Mutation (SNP) | VAF 10/39 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs768200676, COSV55918988; called by muse, mutect2, varscan2
- TYR | c.776A>T p.N259I | Missense Mutation (SNP) | VAF 38/132 reads (29%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.94); catalogued as COSV54486740; called by muse, mutect2, varscan2
- USP37 | c.1831G>A p.A611T | Missense Mutation (SNP) | VAF 89/248 reads (36%) | SIFT tolerated (0.2); PolyPhen benign (0.003); catalogued as COSV51447524; called by muse, mutect2, varscan2
- USP9X | c.5359A>T p.K1787* | Nonsense Mutation (SNP) | VAF 10/126 reads (8%) | catalogued as COSV61075559; called by muse, mutect2
- XIRP1 | c.1307G>C p.G436A | Missense Mutation (SNP) | VAF 37/81 reads (46%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV61141602; called by muse, mutect2, varscan2
- ZNF766 | c.1277T>G p.L426R | Missense Mutation (SNP) | VAF 74/211 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63010339; called by muse, mutect2, varscan2
- PIK3R1 | c.1777_1779del p.K593del (on ENST00000521381 / NM_181523.3; = p.K323del on NM_181504.4) | In Frame Del (DEL) | VAF 147/414 reads (36%) | called by pindel, varscan2
- PIK3R1 | c.1924dup p.R642Pfs*12 (on ENST00000521381 / NM_181523.3; = p.R372Pfs*12 on NM_181504.4) | Frame Shift Ins (INS) | VAF 44/218 reads (20%) | called by mutect2, varscan2
- RBBP6 | c.995_997del p.L332del | In Frame Del (DEL) | VAF 170/444 reads (38%) | called by mutect2, pindel, varscan2
- VPS13A | c.6733_6737del p.L2245Ffs*9 | Frame Shift Del (DEL) | VAF 23/85 reads (27%) | called by mutect2, pindel, varscan2
- CALM3 | c.108G>A p.V36= | Silent (SNP) | VAF 14/68 reads (21%) | catalogued as rs1173698699, COSV52195144; called by muse, mutect2, varscan2
- FRMPD4 | c.3786G>A p.E1262= | Silent (SNP) | VAF 32/75 reads (43%) | catalogued as COSV66223996; called by muse, mutect2, varscan2
- IQGAP2 | c.3363C>A p.I1121= | Silent (SNP) | VAF 35/102 reads (34%) | catalogued as COSV57183214; called by muse, mutect2, varscan2
- MROH2B | c.687C>T p.Y229= | Silent (SNP) | VAF 35/182 reads (19%) | catalogued as rs1201772851, COSV68185301, COSV68187253; called by muse, mutect2, varscan2
- MYL1 | c.60G>T p.P20= | Silent (SNP) | VAF 6/36 reads (17%) | catalogued as rs148686005; called by mutect2, varscan2
- OR1A2 | c.762G>A p.T254= | Silent (SNP) | VAF 51/162 reads (31%) | catalogued as rs755910705, COSV67936845; called by muse, mutect2
- PRAM1 | c.1752G>A p.G584= | Silent (SNP) | VAF 16/58 reads (28%) | catalogued as rs180927898, COSV55317310; called by muse, mutect2, varscan2
- PTH1R | c.996C>T p.P332= | Silent (SNP) | VAF 16/47 reads (34%) | catalogued as rs201912453, COSV57317994; called by muse, mutect2, varscan2
- RUVBL1 | c.744G>A p.A248= | Silent (SNP) | VAF 9/135 reads (7%) | catalogued as rs1262649177, COSV59476235, COSV59477336; called by muse, mutect2
- SIPA1L2 | c.1890G>A p.A630= | Silent (SNP) | VAF 58/305 reads (19%) | catalogued as rs559549937, COSV53400597; called by muse, mutect2, varscan2
- SLC18A3 | c.1230C>T p.D410= | Silent (SNP) | VAF 6/38 reads (16%) | catalogued as rs1167098481, COSV60333629; called by muse, mutect2
- SPRED2 | c.1065G>A p.S355= | Silent (SNP) | VAF 24/57 reads (42%) | catalogued as rs766341539, COSV62692967; called by muse, mutect2, varscan2
- TMEM8B | c.132C>T p.N44= | Silent (SNP) | VAF 19/58 reads (33%) | catalogued as rs770509336, COSV65078092; called by muse, mutect2, varscan2
- TRIM35 | c.1362C>T p.H454= | Silent (SNP) | VAF 21/50 reads (42%) | catalogued as rs774531348, COSV59524174; called by muse, mutect2, varscan2
- USP9X | c.3054C>T p.I1018= | Silent (SNP) | VAF 25/340 reads (7%) | catalogued as COSV61075547; called by muse, mutect2
- ZNF461 | c.1581C>T p.C527= | Silent (SNP) | VAF 40/224 reads (18%) | catalogued as rs561974097, COSV100831429, COSV64454901; called by muse, mutect2, varscan2
- ZNF490 | c.1140C>T p.H380= | Silent (SNP) | VAF 50/137 reads (36%) | catalogued as rs559788529, COSV61007051; called by muse, mutect2, varscan2
- MARCHF1 | c.-322-86005G>A | Intron (SNP) | VAF 85/214 reads (40%) | catalogued as rs1031772747, COSV72277762; called by muse, mutect2, varscan2
